Somatic mutation profile of tumor specimen TCGA-V1-A8MU-01A (aliquot TCGA-V1-A8MU-01A-11D-A377-08) from TCGA case TCGA-V1-A8MU, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8MU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5264c0b6-86d6-48da-a3d9-adb2cff74ab2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A8MU-10A (Blood Derived Normal), aliquot TCGA-V1-A8MU-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd3a74b6-15f5-466b-a99b-aea208943662

The open-access MAF lists 35 somatic variants for this specimen: 21 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 10, Frame Shift Del 2, Frame Shift Ins 2, 3'UTR 2, Splice Site 1, Splice Region 1, Nonsense Mutation 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.2424A>G p.A808= | Splice Region (SNP) | VAF 14/55 reads (25%) | catalogued as rs995022613, COSV99176552; called by muse, mutect2, varscan2
- ARL13B | c.1189C>G p.L397V (on ENST00000394222 / NM_001174150.2; = p.L290V on NM_144996.4) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100115245; called by muse, mutect2, varscan2
- BICRAL | c.3042C>G p.I1014M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV58408868; called by muse, mutect2
- CTCF | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV50479772, COSV99864628; called by muse, mutect2, varscan2
- EHHADH | c.605del p.P202Qfs*17 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | catalogued as rs1216721280; called by mutect2, pindel, varscan2
- KCNB1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.767); catalogued as COSV100870403; called by muse, mutect2, varscan2
- MOGAT2 | c.942C>A p.N314K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1403241301, COSV99549399; called by muse, mutect2
- NAV3 | c.1634G>A p.S545N | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57102301, COSV57103271; called by muse, mutect2
- NR1I3 | c.239-1G>T p.X80_splice | Splice Site (SNP) | VAF 20/76 reads (26%) | catalogued as COSV100915534; called by muse, mutect2, varscan2
- OR12D3 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV101011154; called by muse, mutect2
- OR4K2 | c.479T>G p.V160G | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100064214; called by muse, mutect2, varscan2
- PCDHA8 | c.1508C>A p.S503* | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as rs376777545, COSV100969187; called by muse, mutect2, varscan2
- PCDHB7 | c.1688A>G p.Y563C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50773566, COSV99176234; called by muse, mutect2, varscan2
- TRIM42 | c.215A>G p.N72S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs1440081729, COSV99648072; called by muse, mutect2, varscan2
- TTC7A | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs532590528, COSV99766144; called by muse, mutect2, varscan2
- ZNF536 | c.2413C>T p.R805W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs749973474, COSV62823845; called by muse, mutect2, varscan2
- IKBIP | c.781_787del p.L261* | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- KMT2A | c.2206dup p.R736Kfs*7 | Frame Shift Ins (INS) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- LLGL1 | c.1075dup p.Q359Pfs*95 | Frame Shift Ins (INS) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- MUC2 | c.198C>G p.D66E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- BNIPL | c.405G>A p.L135= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1426103369, COSV99639317; called by muse, mutect2, varscan2
- DNAH17 | c.7011C>T p.T2337= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1439669797, COSV67753136; called by muse, mutect2
- ITGAX | c.1719G>A p.A573= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs763900209, COSV99191515; called by muse, mutect2, varscan2
- KCTD8 | c.786G>A p.P262= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs1405428652, COSV100759266; called by muse, mutect2, varscan2
- NFASC | c.813C>T p.S271= (on ENST00000339876 / NM_001378329.1; = p.S282= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs140997318; called by muse, mutect2, varscan2
- PCDHA7 | c.1533C>T p.H511= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as rs1359534891, COSV100971173; called by muse, mutect2, varscan2
- PTCHD3 | c.810C>T p.Y270= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs376677291; called by muse, mutect2, varscan2
- SEC23B | c.324C>T p.A108= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as rs771580511, COSV99357492; called by muse, mutect2, varscan2
- SNAP47 | c.543G>A p.T181= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs139457264, COSV100247972; called by muse, mutect2, varscan2
- TGFBR3 | c.2118G>A p.E706= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as rs1405611654; called by muse, mutect2
- ATE1 | c.942+971C>G | Intron (SNP) | VAF 10/42 reads (24%) | catalogued as rs770622025, COSV99816827; called by muse, mutect2, varscan2
- CRYAB | chr11:111913472 A>G | 5'Flank (SNP) | VAF 34/158 reads (22%) | catalogued as COSV99909760; called by muse, mutect2, varscan2
- NUPR1 | c.*1_*2del | 3'UTR (DEL) | VAF 20/131 reads (15%) | called by pindel, varscan2
- RRP7A | c.*3853C>T | 3'UTR (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
